Somatic mutation profile of tumor specimen TCGA-BG-A0YU-01A (aliquot TCGA-BG-A0YU-01A-21D-A10M-09) from TCGA case TCGA-BG-A0YU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 37.4 years (13,644 days).
Specimen TCGA-BG-A0YU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d78853d0-ac3c-476d-b5bc-00cc4bb0da97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0YU-10A (Blood Derived Normal), aliquot TCGA-BG-A0YU-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efce7c74-4ceb-409c-9a43-4b8490695651

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, Nonsense Mutation 4, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 51/102 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RRAS2 | c.216A>C p.Q72H | Missense Mutation (SNP) | VAF 21/42 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV56329221, COSV56329422; called by muse, mutect2, varscan2
- ACOT11 | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100650492, COSV59347398; called by muse, mutect2, varscan2
- AKT1 | c.238T>C p.W80R | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV62571792, COSV62572815; called by muse, mutect2, varscan2
- CAMKV | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV56554890; called by muse, mutect2, varscan2
- EPB41L3 | c.3004G>A p.V1002M | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as rs758321771, COSV59449318; called by muse, mutect2
- ERBB3 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.697); catalogued as COSV57248597; called by muse, mutect2, varscan2
- GRIA1 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1194364279, COSV53597870; called by muse, mutect2, varscan2
- LAMC2 | c.1552C>T p.Q518* | Nonsense Mutation (SNP) | VAF 45/91 reads (49%) | catalogued as COSV51454331; called by muse, mutect2, varscan2
- LRRC37A3 | c.4597G>A p.E1533K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.622); catalogued as rs772960790, COSV58534895; called by muse, mutect2, varscan2
- NLRP8 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.879); catalogued as rs145352424, COSV52585687; called by muse, mutect2, varscan2
- PIKFYVE | c.2840C>T p.P947L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs374685821; called by muse, mutect2, varscan2
- SLC12A5 | c.1773C>A p.C591* (on ENST00000454036 / NM_001134771.2; = p.C568* on NM_020708.5) | Nonsense Mutation (SNP) | VAF 86/193 reads (45%) | catalogued as COSV54791475; called by muse, mutect2, varscan2
- SLC44A3 | c.1375C>T p.Q459* (on ENST00000271227 / NM_001114106.3; = p.Q411* on NM_152369.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 27/75 reads (36%) | catalogued as COSV54729275; called by muse, mutect2, varscan2
- SORCS2 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs371760048; called by muse, mutect2
- UROD | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 68/150 reads (45%) | catalogued as rs1412728348, COSV55799659; called by muse, mutect2, varscan2
- USH1G | c.1268A>G p.D423G | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV58881402; called by muse, mutect2, varscan2
- FIGNL1 | c.715_716insT p.N239Ifs*6 | Frame Shift Ins (INS) | VAF 50/125 reads (40%) | called by mutect2, pindel*, varscan2*
- DIO3 | c.138C>A p.L46= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV63773409; called by muse, mutect2, varscan2
- KCNA10 | c.1065G>A p.S355= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as rs566195238, COSV63904206; called by muse, mutect2, varscan2
- MAGEA11 | c.669T>C p.H223= | Silent (SNP) | VAF 61/167 reads (37%) | catalogued as COSV60754981; called by muse, mutect2, varscan2
- MUS81 | c.1647C>T p.P549= | Silent (SNP) | VAF 20/226 reads (9%) | catalogued as COSV57258726; called by muse, mutect2
- PTPRO | c.144C>T p.D48= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs755731862, COSV55506898, COSV99840497; called by muse, mutect2, varscan2
- TMEM67 | c.93T>G p.P31= | Silent (SNP) | VAF 71/210 reads (34%) | catalogued as COSV60037914; called by muse, mutect2, varscan2
- UNC5D | c.2061C>T p.A687= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as rs754886431, COSV54783747; called by muse, mutect2, varscan2
- SLC22A20P | n.652A>G | RNA (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
